Somatic mutation profile of tumor specimen MMRF_1484_2_BM_CD138pos (aliquot MMRF_1484_2_BM_CD138pos_T1_KHS5U_L09515) from MMRF case MMRF_1484, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 72.4 years (26,439 days).
Specimen MMRF_1484_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f6f88f36-84ef-4a2f-a3b4-ed9ad211ba43.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1484_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1484_1_PB_Whole_C3_KBS5U_L03002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cf42e83f-3da3-4a41-a5c6-bcef92255c61

The open-access MAF lists 83 somatic variants for this specimen: 40 protein-altering or splice-affecting, 6 silent, 37 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, 3'UTR 20, Intron 10, Silent 6, RNA 2, 3'Flank 2, 5'UTR 2, In Frame Del 2, Nonsense Mutation 1, Frame Shift Del 1, Splice Site 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTG1 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 37/235 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.988); catalogued as rs375159565; called by muse, mutect2, varscan2
- ATP7B | c.3670C>T p.R1224W | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs746893370; called by muse, mutect2, varscan2
- COMMD3-BMI1 | c.23A>C p.Q8P | Missense Mutation (SNP) | VAF 26/158 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.347); catalogued as COSV64958912; called by muse, mutect2, varscan2
- DDX56 | c.212A>G p.H71R | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.021); catalogued as rs542305571; called by muse, mutect2, varscan2
- GPR139 | c.55C>G p.P19A | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); catalogued as rs1383243009; called by muse, mutect2
- HUNK | c.1627G>A p.G543R | Missense Mutation (SNP) | VAF 42/230 reads (18%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.12); catalogued as rs532775196, COSV54235037; called by muse, mutect2, varscan2
- IGHV2-70 | c.313A>C p.N105H | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); catalogued as rs377238058; called by muse, varscan2
- IGHV2-70 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs368184313; called by muse, mutect2, varscan2
- ITGA2B | c.880A>T p.T294S | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.436); catalogued as COSV52232183; called by muse, varscan2
- OR2B6 | c.649T>A p.S217T | Missense Mutation (SNP) | VAF 48/244 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.163); catalogued as rs1317600991; called by muse, mutect2, varscan2
- OR4C12 | c.431C>T p.A144V | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.005); catalogued as COSV100078540; called by muse, mutect2
- PCLO | c.12275C>T p.T4092I | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV61632431; called by muse, mutect2, varscan2
- SLC17A1 | c.1067C>T p.P356L | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.119); catalogued as rs1453748397; called by muse, mutect2, varscan2
- SLC5A8 | c.8C>G p.T3R | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.011); catalogued as rs1400867028; called by muse, mutect2
- ZNF525 | c.914A>G p.D305G | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1051942833; called by muse, mutect2, varscan2
- ABCC6 | c.1054_1056del p.L352del | In Frame Del (DEL) | VAF 10/86 reads (12%) | called by pindel, varscan2
- ABCC9 | c.1502G>A p.G501D | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BRD2 | c.112C>A p.L38I | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- CDH4 | c.880A>G p.T294A | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- COL3A1 | c.3861G>C p.L1287F | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- ERCC6 | c.4021G>A p.V1341M | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- FAM78B | c.370C>G p.L124V | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FYB2 | c.612A>T p.K204N | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- HIP1R | c.2915C>T p.S972F | Missense Mutation (SNP) | VAF 30/159 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HOXB9 | c.559A>G p.K187E | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HUWE1 | c.9599T>G p.L3200R | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- IGHV2-70D | c.52T>G p.L18V | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.188); called by muse, varscan2
- IGLV4-3 | c.330C>G p.H110Q | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- LYN | c.71T>A p.V24E | Missense Mutation (SNP) | VAF 66/338 reads (20%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, varscan2
- OR10G8 | c.856G>A p.V286M | Missense Mutation (SNP) | VAF 36/235 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- PIK3C3 | c.763G>A p.V255I | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PLPPR5 | c.735T>A p.Y245* | Nonsense Mutation (SNP) | VAF 20/112 reads (18%) | called by muse, mutect2, varscan2
- RFX5 | c.1463C>T p.A488V | Missense Mutation (SNP) | VAF 44/243 reads (18%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- STAT5B | c.1123A>T p.S375C | Missense Mutation (SNP) | VAF 22/257 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); called by muse, mutect2
- SYNE2 | c.6714+2T>G p.X2238_splice | Splice Site (SNP) | VAF 18/94 reads (19%) | called by muse, mutect2, varscan2
- TAC1 | c.306del p.F103Lfs*4 | Frame Shift Del (DEL) | VAF 11/47 reads (23%) | called by mutect2, pindel, varscan2
- TERF2IP | c.92_94del p.F31del | In Frame Del (DEL) | VAF 22/152 reads (14%) | called by mutect2, pindel, varscan2
- TLR8 | c.833T>C p.I278T (on ENST00000218032 / NM_138636.5; = p.I296T on NM_016610.4) | Missense Mutation (SNP) | VAF 5/105 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- WNK2 | c.2086C>G p.Q696E | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- ZNF236 | c.2551T>A p.F851I | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- DNAH6 | c.135A>G p.E45= | Silent (SNP) | VAF 26/185 reads (14%) | called by muse, mutect2, varscan2
- H3C7 | c.66C>A p.A22= | Silent (SNP) | VAF 28/198 reads (14%) | called by muse, mutect2, varscan2
- KIAA1109 | c.11964A>G p.K3988= | Silent (SNP) | VAF 35/143 reads (24%) | called by muse, mutect2, varscan2
- LRRC19 | c.420A>T p.V140= | Silent (SNP) | VAF 5/34 reads (15%) | called by muse, mutect2, varscan2
- MGAM | c.2835C>T p.L945= | Silent (SNP) | VAF 7/129 reads (5%) | catalogued as COSV72073646; called by muse, mutect2
- UNC80 | c.3162G>A p.T1054= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as rs367811380, COSV55893266; called by muse, mutect2
- AMIGO1 | chr1:109504761 A>C | 3'Flank (SNP) | VAF 15/110 reads (14%) | called by muse, mutect2, varscan2
- AMIGO2 | c.*784T>C | 3'UTR (SNP) | VAF 32/197 reads (16%) | called by muse, mutect2, varscan2
- BEND3 | c.*1056G>A | 3'UTR (SNP) | VAF 8/160 reads (5%) | called by muse, mutect2
- BMPER | c.*1939G>T | 3'UTR (SNP) | VAF 10/45 reads (22%) | catalogued as COSV51833884; called by muse, mutect2, varscan2
- BTBD3 | chr20:11890728 G>A | 5'Flank (SNP) | VAF 6/42 reads (14%) | called by muse, mutect2, varscan2
- C11orf87 | c.*4457C>T | 3'UTR (SNP) | VAF 10/67 reads (15%) | called by muse, mutect2, varscan2
- CPEB4 | c.-573C>A | 5'UTR (SNP) | VAF 12/106 reads (11%) | catalogued as rs926172514; called by muse, mutect2, varscan2
- DEFB118 | c.*657C>G | 3'UTR (SNP) | VAF 5/33 reads (15%) | called by muse, mutect2
- DEGS2 | c.*177C>T | 3'UTR (SNP) | VAF 23/116 reads (20%) | catalogued as rs1008600907; called by muse, mutect2, varscan2
- FAM131B | c.*2188G>A | 3'UTR (SNP) | VAF 20/91 reads (22%) | catalogued as rs113104457; called by muse, mutect2, varscan2
- G2E3 | c.*1860T>A | 3'UTR (SNP) | VAF 6/49 reads (12%) | called by muse, mutect2, varscan2
- GABRA2 | c.187+21069G>C | Intron (SNP) | VAF 11/64 reads (17%) | called by muse, mutect2, varscan2
- GNL3L | c.-47-66A>C | Intron (SNP) | VAF 21/60 reads (35%) | called by muse, mutect2, varscan2
- IARS1 | c.-8+909A>G | Intron (SNP) | VAF 7/55 reads (13%) | called by muse, mutect2
- KIF1A | c.*1961G>A | 3'UTR (SNP) | VAF 9/89 reads (10%) | catalogued as rs541275784; called by muse, mutect2, varscan2
- KNG1 | c.*1004C>T | 3'UTR (SNP) | VAF 7/51 reads (14%) | called by muse, mutect2, varscan2
- LTB | c.162+86del | Intron (DEL) | VAF 8/63 reads (13%) | called by pindel, varscan2
- LTB | c.162+80T>G | Intron (SNP) | VAF 8/64 reads (13%) | called by muse, varscan2
- MAFK | c.*1394T>G | 3'UTR (SNP) | VAF 24/170 reads (14%) | called by muse, mutect2, varscan2
- NALCN | c.*301T>G | 3'UTR (SNP) | VAF 11/47 reads (23%) | called by muse, mutect2, varscan2
- P2RX1 | c.137+147G>T | Intron (SNP) | VAF 28/178 reads (16%) | called by muse, mutect2, varscan2
- PGD | c.*11C>G | 3'UTR (SNP) | VAF 41/248 reads (17%) | called by muse, mutect2, varscan2
- PIP4K2A | c.*476T>G | 3'UTR (SNP) | VAF 4/25 reads (16%) | catalogued as rs200238710, COSV60540026; called by muse, varscan2
- PNPLA8 | c.*1335A>G | 3'UTR (SNP) | VAF 3/43 reads (7%) | called by muse, mutect2
- PRPF38B | c.*528A>G | 3'UTR (SNP) | VAF 6/36 reads (17%) | called by muse, mutect2, varscan2
- PRPF38B | c.*643A>G | 3'UTR (SNP) | VAF 8/53 reads (15%) | called by muse, mutect2, varscan2
- S100A8 | c.-22-121G>C | Intron (SNP) | VAF 7/49 reads (14%) | catalogued as rs910779259; called by muse, mutect2
- SCAMP2 | c.*394G>T | 3'UTR (SNP) | VAF 14/107 reads (13%) | called by muse, mutect2, varscan2
- SPCS2P4 | n.639C>T | RNA (SNP) | VAF 15/109 reads (14%) | called by muse, mutect2, varscan2
- SPEF2 | c.4448-3558A>T | Intron (SNP) | VAF 7/159 reads (4%) | catalogued as rs1423610484; called by muse, mutect2
- SSPOP | n.10801T>G | RNA (SNP) | VAF 16/88 reads (18%) | called by muse, mutect2, varscan2
- STN1 | c.*57G>A | 3'UTR (SNP) | VAF 19/174 reads (11%) | called by muse, mutect2, varscan2
- TRIM73 | chr7:75414888 T>G | 3'Flank (SNP) | VAF 8/56 reads (14%) | catalogued as rs397392; called by muse, mutect2, varscan2
- TSPAN19 | c.-3A>C | 5'UTR (SNP) | VAF 16/97 reads (16%) | called by muse, mutect2, varscan2
- UBAC2 | c.31+62G>T | Intron (SNP) | VAF 21/112 reads (19%) | called by muse, mutect2, varscan2
- ULK2 | c.*40+1279C>G | Intron (SNP) | VAF 6/58 reads (10%) | called by muse, varscan2
- ZNF439 | c.*167G>T | 3'UTR (SNP) | VAF 20/142 reads (14%) | called by muse, varscan2
